Somatic mutation profile of tumor specimen 0DH9LN from CCDI case PBBUCV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.4 years (5,245 days).
Specimen 0DH9LN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 485a95b8-b5a8-44f0-b6f2-b1b0e1067f77.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DH9KX (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f7456acc-e418-4d1b-850c-31e3ba0ffe3a

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Intron 3, Silent 2, Splice Site 1, In Frame Del 1, Frame Shift Ins 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFAP46 | c.2266C>T p.R756W | Missense Mutation (SNP) | VAF 25/804 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1008283087; called by muse, mutect2
- DPEP3 | c.119C>T p.P40L | Missense Mutation (SNP) | VAF 201/511 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs1309765137, COSV99262815; called by muse, mutect2, varscan2
- POLRMT | c.3020G>A p.R1007H | Missense Mutation (SNP) | VAF 139/601 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs143468194; called by muse, mutect2, varscan2
- POTEG | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 60/676 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.346); catalogued as rs1438859427; called by muse, mutect2
- ATP4A | c.2606G>A p.G869D | Missense Mutation (SNP) | VAF 22/606 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CHUK | c.587A>T p.K196M | Missense Mutation (SNP) | VAF 158/368 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- KMT2C | c.57dup p.E20Rfs*39 | Frame Shift Ins (INS) | VAF 218/597 reads (37%) | called by mutect2, pindel, varscan2
- MYO10 | c.1997T>A p.V666E | Missense Mutation (SNP) | VAF 40/604 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NEXMIF | c.4280T>A p.F1427Y | Missense Mutation (SNP) | VAF 166/343 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- OBSCN | c.16024G>A p.A5342T | Missense Mutation (SNP) | VAF 170/422 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- PDE3A | c.3241C>T p.Q1081* | Nonsense Mutation (SNP) | VAF 124/541 reads (23%) | called by muse, mutect2, varscan2
- SETD2 | c.4733_4747del p.E1578_E1582del | In Frame Del (DEL) | VAF 71/507 reads (14%) | called by mutect2, pindel, varscan2
- SLC22A1 | c.1082A>G p.Y361C | Missense Mutation (SNP) | VAF 248/444 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUPT16H | c.875T>C p.V292A | Missense Mutation (SNP) | VAF 258/548 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TRIM33 | c.1860+1G>C p.X620_splice | Splice Site (SNP) | VAF 146/320 reads (46%) | called by muse, mutect2, varscan2
- XRCC6 | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 275/662 reads (42%) | SIFT tolerated (0.68); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CFAP70 | c.1011G>A p.S337= | Silent (SNP) | VAF 195/464 reads (42%) | catalogued as rs145436804; called by muse, mutect2, varscan2
- RNASE13 | c.126T>A p.V42= | Silent (SNP) | VAF 185/591 reads (31%) | called by muse, mutect2, varscan2
- CBFA2T3 | c.151+36396G>A | Intron (SNP) | VAF 242/559 reads (43%) | called by muse, mutect2, varscan2
- CCDC137 | c.498-34T>C | Intron (SNP) | VAF 173/512 reads (34%) | called by muse, mutect2, varscan2
- SEC11C | c.*83dup | 3'UTR (INS) | VAF 62/185 reads (34%) | called by mutect2, pindel, varscan2
- SLC39A4 | c.193-143G>A | Intron (SNP) | VAF 6/144 reads (4%) | catalogued as rs1172113497; called by muse, mutect2
